Surgical pathology report (de-identified scan), TCGA case TCGA-24-1544, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1544-01A (Primary Tumor).

[page 1 of 5]
Other Related Clinical Data:

DIAGNOSIS: OVARY, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY
- INVOLVED BY ADENOCARCINOMA (SEE COMMENT)

FALLOPIAN TUBE, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY
- INVOLVED BY ADENOCARCINOMA

OVARY, LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- INVOLVED BY ADENOCARCINOMA (SEE COMMENT)

FALLOPIAN TUBE, LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- INVOLVED BY ADENOCARCINOMA

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- BENIGN ENDOMETRIAL POLYP

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY
- FOCALLY INVOLVED BY ADENOCARCINOMA

LYMPH NODE, LEFT EXTERNAL ILIAC, EXCISION
- METASTATIC ADENOCARCINOMA IN ONE OF TWO LYMPH NODES (1/2)

OMENTUM, OMENTECTOMY

[page 2 of 5]
[REDACTED]

- INVOLVED BY ADENOCARCINOMA

OMENTUM, GASTROCOLIC, OMENTECTOMY
- INVOLVED BY ADENOCARCINOMA

LARGE INTESTINE, SIGMOID COLON, BIOPSY
- INVOLVED BY ADENOCARCINOMA

LARGE INTESTINE, RECTOSIGMOID COLON, BIOPSY
- INVOLVED BY ADENOCARCINOMA

BLADDER, SEROSA, BIOPSY
- INVOLVED BY ADENOCARCINOMA

[REDACTED] By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

Report Electronically Reviewed and Signed Out By [REDACTED]

Intraoperative Consultation: An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to the O.R. to pickup 'left ovary' composed of an ovarian mass measuring 14 x 9 x 6.5 cm and weighing 549 grams. Sections show multiloculated cut surfaces with areas of necrosis. Multiple areas are submitted for frozen. Tissue submitted for tumor bank; all rest for permanents," by [REDACTED]

FS1: Ovary, left, excision

- "Adenocarcinoma, favor Mullerian, [REDACTED]"

[REDACTED] Microscopic Description and Comment: Histologic sections of the invasive adenocarcinoma in both the right and left ovaries show predominantly a papillary serous pattern. In several foci, the papillae are fused so that solid sheets of cells are seen. In one focus in the left ovary, the tumor is composed of sheets of cells with variably cleared cytoplasm. These latter elements also focally exhibit spindled features; nonetheless, we regard them as most consistent with a minor clear cell component. Other foci of the tumor exhibit mucinous features with irregular nests, glands and clusters of neoplastic mucinous epithelial cells resting in mucin pools. In many of the metastatic foci, including the gastrocolic omentum, the rectosigmoid nodule, the bladder serosa, and in both fallopian tubes, this latter component is conspicuous. Irrespective of the histologic pattern that predominates in any given location, psammomatous calcification is invariably present. Tumor is also present on the posterior serosal surface of the uterus and in the posterior uterine peritoneal reflection. It is possible that this tumor may have arisen in an extra-mullerian site; however, despite the unusual mucinous elements in this tumor, we believe that this process is best interpreted as a primary ovarian papillary serous carcinoma with multifocal intraabdominal spread and lymph nodal metastasis. Recognition of the mucinous elements in this case is important, because of the likelihood that subsequent metastases will contain or be dominated by this pattern of disease. [REDACTED] has reviewed this case and agrees with this interpretation. [REDACTED]

[REDACTED] History: The patient is a [REDACTED] with carcinomatosis of the abdomen and a large left ovarian mass. Operative procedure: Examination under anesthesia, laparotomy, omentectomy, total abdominal hysterectomy/bilateral salpingo-oophorectomy, left ureterolysis, radical tumor debulking.

[page 3 of 5]
Specimen(s) Received:

A: OMENTUM, ROUTINE
B: LEFT OVARY
C: LEFT EXT. ILIAC LYMPH NODE
D: BLADDER SEROSA
E: UTERUS AND CERVIX
F: SIGMOID NODULE
G: BLADDER SEROSA
H: SIGMOID RECTAL NODULE
I: GASTRO-COLIC OMENTUM

Gross Description Received are nine formalin-filled containers labeled with the patient's name. The first container is further labeled "omentum #1." The specimen consists of a 337 gram portion of omentum measuring 18 x 14 x 3 cm. The surface is yellow-tan, nodular and firm, forming a mass measuring 11 x 8 x 4 cm. Other yellow, firm masses measuring up to 3.5 cm are noted within the fatty omental tissue. Cut section shows a mostly solid yellow lobulated and granular cut surface with cysts ranging in size from 2.5 x 2 x 2 cm to 0.5 cm. Some cysts are lined by light yellow necrotic material, and others by hemorrhagic granular tissue. Blocks labeled: A1 and A2 - cystic hemorrhagic area; A3 - necrotic cyst; A4 - mucous cyst; A5 - random unremarkable omentum. [REDACTED]

The second container is further labeled "left ovary (FS1/X1)." The cassette labeled F1 holds tissue measuring 3 x 1.5 x 0.3 cm, composed of grey-yellow friable tissue. The specimen consists of a 549 gram ovary measuring 14 x 9 x 6.5 cm. The surface is smooth, shiny and grey-white with focal papillary excrescences, measuring up to 1 cm in diameter which are tan in color. A surface multiloculated cyst measures 6 x 4.5 x 3 cm and contains yellow-green fluid. A definitive fallopian tube is not identified on the surface. Focal peritoneal tissue attached to the surface measures 5 x 4 x 0.3 cm. Cut sections of the ovary show predominantly a solid multiloculated surface with cyst spaces filled with yellow-tan soft tissue and other cyst spaces filled with papillary grey-white tissue. Random sections taken from representative areas. Labeled B1
[REDACTED]

The third container is further labeled "left external iliac lymph node." The specimen consists of two tan-yellow fatty tissue fragments measuring 5 x 2.5 x 1 cm and 3.5 x 1.7 x 0.5 cm. The specimen is dissected to show two tan nodes, the larger measuring 4 cm in length, which is bisected, and the second measures 1.5 cm in length. Labeled C1. Jar 1.

The fourth container is labeled "bladder serosa." The specimen consists of grey-tan papillary tissue fragments with a serosal surface measuring 1.5 x 1.5 x 0.3 cm and 1.3 x 0.7 x 0.2 cm. Wrapped in tissue. [REDACTED]

The fifth container is labeled "uterus, cervix, RSO." The specimen consists of a 93 gram uterus with attached right fallopian tube and ovary. The uterus measures 8 cm in length x 4 cm from cornu to cornu x 3 cm from anterior to posterior. The anterior serosal aspect is predominantly smooth, shiny and purple with three focal tan-white plaques measuring 0.3 cm each in diameter. The posterior surface is similar with the peritoneal surface extending for a distance of 9 cm from the uterine fundus with underlying fibrous tissue extending for a depth of 2 cm distally. This tissue is inked black. The cervical os is ovoid and is covered by a glistening grey-pink smooth surface measuring 3 x 2.5 cm. It has a slit-like os measuring 1 cm in length and 0.2 cm in diameter. No focal lesion is identified. The os is narrowed to a diameter of <0.3 cm. The specimen is bivalved to show an unremarkable endocervical canal measuring 2 cm in length with a Nabothian cyst measuring up to 0.6 cm in diameter. The endometrial cavity is pear-shaped and measures 1.7 cm in width x 2.5 cm in length. It contains an endometrial grey-white glistening polyp measuring 2 cm

[page 4 of 5]
[REDACTED]

in length x 0.8 x 0.8 cm, attached at the fundus of the cavity. The remaining cavity is lined by tan, granular parenchyma measuring up to 0.1 cm in depth. The myometrial wall is unremarkable and measures up to 1.5 cm in thickness. The posterior inked peritoneal tissue is longitudinally sectioned to show grey-white fibrous tissue with focal dark necrotic center measuring 1 x 0.7 x 0.7 cm. The attached right fallopian tube measures 4 cm in length and an average diameter of 0.7 cm, and is wrapped around the surface of a cystic and enlarged ovary measuring 5.5 x 3.5 x 3 cm. The fimbrial surface is firmly attached to the ovarian surface adjacent to which there are papillary excrescences which are tan-brown and focally grey-white and firm over an area measuring 2.5 x 2 cm. The ovary is sectioned to show complete replacement of this parenchyma by grey-white soft, fibrinous tissue measuring 4 x 2.8 x 3 cm. The ovary is extremely friable on sectioning. Sections labeled as follows: E1 - anterior cervix; E2 - posterior cervix; E3 - anterior endometrium with polyp and serosal nodule; E4 - anterior endometrium; E5 - posterior endometrium with polyp; E6 - serosal nodule posterior in uterus; E7 - posterior peritoneal flap distally; E8 - right fallopian tube and portion of ovary with fimbria and puckered surface; E10 and 11 - tumor right ovary; E12 - left fallopian tube remnant. Jar 2.

The sixth container is labeled "sigmoid nodule." The specimen consists of three portions of grey friable fibrillary tissue, each measuring 1.5 x 1.5 x 0.5 cm, 2 x 1.5 x 1 cm and 1.2 x 1 x 0.3 cm. [REDACTED]

The seventh container is labeled "bladder serosa 'B'." The specimen consists of a firm lobular, yellow portion of tissue measuring 2.5 x 1.5 x 1 cm. The surface is covered with fat and the cut section shows yellow-grey nodules measuring 0.7 cm maximally. [REDACTED]

The eighth container is labeled "sigmoid rectal nodule." The specimen consists of a section of tan-brown tissue measuring 1.8 x 1.5 x 0.7 cm. The specimen is firm and sectioning shows a grey-white firm nodule measuring 1 x 1 x 1 cm. [REDACTED]

The ninth container is further labeled "gastrocardiac omentum" and holds a portion of omentum measuring 24 x 9 x 3 cm. The surface shows gray, nodular surface with nodules measuring up to 5 x 3.5 x 3 cm and involving \R\70% of the omentum; Serially sectioning shows yellow-white, firm nodules throughout the omental specimen. [REDACTED]

[REDACTED]

Synopsis SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS 1. A neoplasm is PRESENT 2. The HISTOLOGIC DIAGNOSIS is: Serous adenocarcinoma 3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are: Right and left ovary 4. The FIGO GRADE of the tumor is: III (Tumor composed of >50% solid cellular nests) 5. The NUCLEAR (BRODERS') GRADE of the tumor is: G3 (Poorly-differentiated) 6. Tumor IS identified on the ovarian surface(s). 7 Tumor DOES invade the mesovarium. 8. Tumor DOES invade the adjacent fallopian tube. 9. Tumor DOES invade the pelvic soft tissue. 10. Tumor involvement of the pelvic peritoneum is PRESENT. 11. Metastatic involvement of the EXTRAPELVIC PERITONEUM is PRESENT. 12. Metastatic involvement of the omentum is PRESENT. 13. The maximum dimension of tumor implants outside the true pelvis is 11 cm 14. Metastatic involvement of the uterine serosa is PRESENT. 15. Metastatic involvement of the endometrium is ABSENT. 16. Regional lymph node metastases are PRESENT. 17. The total number of regional lymph nodes examined is 2 18. The total number of metastatically-involved regional lymph nodes is 1 Extranodal extension by tumor metastases is ABSENT. 19. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:

TNM Scheme FIGO Scheme Definition

[page 5 of 5]
T3c

IIIC

Macroscopic

peritoneal metastasis beyond true pelvis measuring > 2 cm in greatest dimension and regional lymph node metastasis OR

THE REGIONAL LYMPH NODES are classified as: N1 (Nodes contain metastatic tumor)

THE STATUS OF DISTANT TUMOR SITES is classified as: MX (Status cannot be assessed) 20. The

FINAL AJCC/UICC/FIGO STAGE IS: AJCC/UICC/FIGO

IIIC (T3c/N1/M0)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file b31cd8dc-2c61-4787-a380-151961344822 (TCGA-24-1544.2FD78A14-CC3F-4920-9C50-6051579B6AD4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).